Somatic mutation profile of tumor specimen ALCH-AD6R-TTP1-A (aliquot ALCH-AD6R-TTP1-A-1-0-D-A502-36) from ALCHEMIST case ALCH-AD6R, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.8 years (20,010 days).
Specimen ALCH-AD6R-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f750c9cc-ae4d-426e-b08b-2d19703f58cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AD6R-NB1-A (Blood Derived Normal), aliquot ALCH-AD6R-NB1-A-1-0-D-A502-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/961728c0-9dbb-421d-bf18-0266826ebabf

The open-access MAF lists 22 somatic variants for this specimen: 10 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 8, Intron 2, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OR2T4 | c.839T>C p.V280A | Missense Mutation (SNP) | VAF 55/1109 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as rs746143008, COSV63543386; called by muse, mutect2
- PDILT | c.359A>G p.E120G | Missense Mutation (SNP) | VAF 32/694 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.061); catalogued as rs752364490; called by muse, mutect2
- PTPN21 | c.2857G>A p.A953T | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs112928496, COSV60850408; called by muse, mutect2
- RBL1 | c.3170G>A p.R1057Q | Missense Mutation (SNP) | VAF 19/233 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs956951052; called by muse, mutect2
- SLC9A3 | c.1936G>C p.E646Q | Missense Mutation (SNP) | VAF 23/288 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV53799442; called by muse, mutect2
- THBS4 | c.154G>C p.D52H | Missense Mutation (SNP) | VAF 50/976 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); catalogued as rs745758223; called by muse, mutect2
- AMPD2 | c.1811A>G p.Y604C | Missense Mutation (SNP) | VAF 18/307 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- C2CD3 | c.3121C>A p.Q1041K | Missense Mutation (SNP) | VAF 35/226 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- GAD1 | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 38/1250 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2
- ZNF880 | c.1568A>C p.N523T | Missense Mutation (SNP) | VAF 33/277 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- AGBL2 | c.2700A>G p.T900= | Silent (SNP) | VAF 6/123 reads (5%) | called by muse, mutect2
- BUB1B | c.1143G>A p.R381= | Silent (SNP) | VAF 27/424 reads (6%) | called by muse, mutect2
- CETP | c.372G>A p.L124= | Silent (SNP) | VAF 59/992 reads (6%) | called by muse, mutect2
- CNTNAP2 | c.1677G>T p.V559= | Silent (SNP) | VAF 45/531 reads (8%) | catalogued as COSV100663996; called by muse, mutect2
- DPYS | c.1290C>A p.G430= | Silent (SNP) | VAF 42/649 reads (6%) | called by muse, mutect2
- HCN1 | c.2640C>T p.D880= | Silent (SNP) | VAF 84/1016 reads (8%) | catalogued as rs768551046, COSV57506534; called by muse, mutect2
- OR6C74 | c.834T>A p.S278= | Silent (SNP) | VAF 13/347 reads (4%) | called by muse, mutect2
- SOCS2 | c.303C>T p.D101= | Silent (SNP) | VAF 42/600 reads (7%) | catalogued as rs148086876; called by muse, mutect2
- ALK | c.3516-225T>G | Intron (SNP) | VAF 19/244 reads (8%) | called by muse, mutect2
- C4A | chr6:32005762 T>A | 3'Flank (SNP) | VAF 69/372 reads (19%) | called by muse, varscan2
- D2HGDH | c.1141-681C>A | Intron (SNP) | VAF 12/176 reads (7%) | called by muse, mutect2
- TAF1D | c.-115A>G | 5'UTR (SNP) | VAF 58/361 reads (16%) | called by mutect2, varscan2
